Somatic mutation profile of tumor specimen MP2PRT-PAWCEL-TMP1-A (aliquot MP2PRT-PAWCEL-TMP1-A-1-0-D-A80M-36) from MP2PRT case MP2PRT-PAWCEL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,499 days).
Specimen MP2PRT-PAWCEL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a596023-a595-4d6e-8a33-5319c62cc672.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCEL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCEL-NB1-A-1-0-D-A80M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3158a6f1-1154-4d3a-87b2-0ba6f55553ed

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 3, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2049A>T p.R683S | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519723, COSV67569539, COSV67577012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARR3 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 70/472 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs773226154, COSV57203779; called by muse, mutect2, varscan2
- CHD4 | c.2588A>C p.H863P (on ENST00000357008 / NM_001363606.2; = p.H876P on NM_001273.5) | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58913174; called by mutect2, varscan2
- IKZF1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 15/459 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58783774; called by muse, mutect2
- ATP6V0D2 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 138/408 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- DDX4 | c.815A>T p.D272V | Missense Mutation (SNP) | VAF 25/382 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FNDC11 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 175/480 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- IGKV1-37 | chr2:89297259 GTGGGA>CCTGG | Missense Mutation (DEL) | VAF 34/231 reads (15%) | called by pindel, varscan2*
- IGKV3D-11 | chr2:90173408 GGCATCCCACAGT>CCGGGAG | Missense Mutation (DEL) | VAF 43/193 reads (22%) | called by pindel, varscan2*
- OR5T2 | c.851T>G p.L284R | Missense Mutation (SNP) | VAF 149/352 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITLN2 | c.438C>T p.Y146= | Silent (SNP) | VAF 25/330 reads (8%) | catalogued as rs1330430067, COSV63537874; called by muse, mutect2
- GRM5 | c.661+38163G>A | Intron (SNP) | VAF 13/311 reads (4%) | called by muse, mutect2
- IGKV3D-20 | chr2:90039480 del CC | 3'Flank (DEL) | VAF 43/71 reads (61%) | called by mutect2, pindel, varscan2
- SPACA7 | c.94+6002G>A | Intron (SNP) | VAF 144/369 reads (39%) | catalogued as rs529892628; called by muse, mutect2, varscan2
- SYT7 | c.215+8870C>T | Intron (SNP) | VAF 227/413 reads (55%) | called by muse, mutect2, varscan2
